Surgical pathology report (de-identified scan), TCGA case TCGA-85-A511, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-A511-01A (Primary Tumor).

ICD-0-3

Carcinoma, squamous cell, NOS 8070/3
Site: Lung, Lower lobe C34.3

hw
11/8/12

Gross Description:

Microscopic Description:

Diagnosis Details:

Comments:

Formatted Path Reports: LUNG TISSUE CHECKLIST

Specimen type: Lobectomy

Tumor site: Lung

Tumor size: 6 x 6 x 6 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Visceral pleura

Other tumor nodules: Not specified

Lymph nodes: 1/3 positive for metastasis (Intrathoracical 1/3)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: Left- lower

I/PAA Discrepancy		
Case is a Relapse		
Reviewed on: 11/8/12	Date Reviewed: 11/8/12	

Source: NCI Genomic Data Commons file eadd59a7-c8b9-40b0-9787-a630f2c8cbb9 (TCGA-85-A511.63785892-9586-4C23-A6F6-794DF6D4A2F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).